Somatic mutation profile of cancer-model specimen HCM-CSHL-0061-C18-85A (3D Organoid; aliquot HCM-CSHL-0061-C18-85A-01D-A768-36), derived from the primary tumor of HCMI case HCM-CSHL-0061-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,277 days).
Specimen HCM-CSHL-0061-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1849abd-1798-4aae-8563-104c08abb3be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0061-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0061-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08066403-06ec-4d05-bccf-13607f07f7b7

The open-access MAF lists 136 somatic variants for this specimen: 102 protein-altering or splice-affecting, 23 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 23, Nonsense Mutation 5, Intron 4, RNA 3, 5'Flank 3, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 263/264 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC099489.1 | c.4183G>A p.V1395M | Missense Mutation (SNP) | VAF 78/618 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.171); catalogued as rs1311438842, COSV60865433; called by muse, mutect2, varscan2
- BRINP3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs144952455, COSV66521744; called by muse, mutect2, varscan2
- CEND1 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs762710448, COSV57192414; called by muse, mutect2, varscan2
- CEP128 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs115620263; called by muse, mutect2, varscan2
- CHD3 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs1042654149; called by muse, varscan2
- COL5A1 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 192/399 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs768531108, COSV65673999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSDE1 | c.911C>T p.T304M (on ENST00000358528 / NM_001007553.3; = p.T273M on NM_007158.6) | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs542388231, COSV54755638; called by muse, mutect2, varscan2
- DACT1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 463/464 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773256045; called by muse, mutect2, varscan2
- DCBLD1 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 127/602 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs779698146; called by muse, mutect2, varscan2
- DGKB | c.486C>G p.D162E | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51775651; called by muse, mutect2, varscan2
- DNAI2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 183/265 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as rs752440806, COSV56761525; called by muse, mutect2, varscan2
- DNASE1L1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 147/238 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs781833694; called by muse, mutect2, varscan2
- EDC3 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as rs148327581; called by muse, mutect2
- EMC2 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.712); catalogued as rs1243054409, COSV55209864; called by muse, mutect2
- FAM47B | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 257/572 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs778028004, COSV61453478; called by muse, mutect2, varscan2
- FAT2 | c.9778G>A p.E3260K | Missense Mutation (SNP) | VAF 96/342 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs758791616, COSV55823617; called by muse, mutect2, varscan2
- FLNC | c.5984G>A p.R1995H | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs371508414; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA3 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100943343; called by muse, mutect2, varscan2
- GLI3 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 244/648 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as rs529978440; called by muse, mutect2, varscan2
- GRIN2D | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 125/348 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.607); catalogued as rs1382484564; called by muse, mutect2, varscan2
- HIP1R | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs749364683; called by muse, mutect2, varscan2
- HMCN2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1286308441, COSV70279975; called by muse, mutect2, varscan2
- INF2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 397/823 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.169); catalogued as rs1049200069, COSV99383740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCF1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 42/441 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763053117, COSV58823313; called by muse, mutect2
- KRTAP4-3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs371581214; called by muse, varscan2
- LRP1B | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63342018; called by muse, mutect2, varscan2
- LRRC37A2 | c.3482G>A p.R1161Q | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs753899745, COSV61003345; called by muse, varscan2
- MSI1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1210006090; called by muse, mutect2, varscan2
- MYLK3 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV101189128; called by muse, mutect2, varscan2
- OBSCN | c.15212C>T p.A5071V | Missense Mutation (SNP) | VAF 32/513 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375341687; called by muse, mutect2
- OR4A5 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 227/396 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV60521838; called by muse, mutect2, varscan2
- OTOF | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs149701372; ClinVar: uncertain significance; called by muse, mutect2
- PDGFRA | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 106/146 reads (73%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as rs774431464, COSV57265740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZD7 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1173857385; called by muse, mutect2, varscan2
- PID1 | c.212C>T p.P71L (on ENST00000354069 / NM_001330156.1; = p.P69L on NM_017933.5) | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs766470127, COSV62476119; called by muse, mutect2, varscan2
- PMFBP1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as rs778219933; called by muse, mutect2, varscan2
- PROM2 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs537196418, COSV100469102, COSV100469421; called by muse, mutect2, varscan2
- REM1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 234/731 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52427424; called by muse, mutect2, varscan2
- RGPD3 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 239/1221 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs763265166; called by muse, mutect2, varscan2
- RP1 | c.4523A>G p.D1508G | Missense Mutation (SNP) | VAF 181/429 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs751429007; called by muse, varscan2
- SACM1L | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613346; called by muse, mutect2, varscan2
- SLC8A2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 120/379 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761837734, COSV52638361; called by muse, mutect2, varscan2
- STK10 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs757877605, COSV51571147; called by muse, mutect2, varscan2
- TBC1D8B | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 51/190 reads (27%) | catalogued as rs749688361; called by muse, mutect2, varscan2
- TMEM132D | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV70593364; called by muse, mutect2, varscan2
- TOP1MT | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 291/374 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563952364; called by muse, mutect2, varscan2
- TRIM67 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 150/231 reads (65%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1402267120; called by muse, mutect2, varscan2
- WNT3A | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 163/272 reads (60%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.455); catalogued as rs1399260520; called by muse, mutect2, varscan2
- ZC4H2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs958668037, COSV100565132, COSV62002663; called by muse, mutect2, varscan2
- ZNF213 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 97/432 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1410444742; called by muse, mutect2, varscan2
- ZNF345 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV59323810, COSV59325519; called by muse, mutect2, varscan2
- ZNF397 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1203968566; called by muse, mutect2, varscan2
- ABCA9 | c.1714G>T p.G572* | Nonsense Mutation (SNP) | VAF 74/245 reads (30%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.3384C>G p.S1128R | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- APC | c.4063dup p.S1355Ffs*20 | Frame Shift Ins (INS) | VAF 218/355 reads (61%) | called by pindel, varscan2
- CBX5 | c.138-3C>G | Splice Region (SNP) | VAF 159/240 reads (66%) | called by muse, mutect2, varscan2
- CEP126 | c.248del p.A84Lfs*57 | Frame Shift Del (DEL) | VAF 43/157 reads (27%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.1962G>T p.R654S | Missense Mutation (SNP) | VAF 126/595 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- DISP1 | c.2622C>G p.C874W | Missense Mutation (SNP) | VAF 312/470 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ECHDC3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FIZ1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GUCY2C | c.523T>A p.W175R | Missense Mutation (SNP) | VAF 149/239 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HECTD4 | c.6545G>A p.G2182E | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD4 | c.6544G>A p.G2182R | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDI1 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- ITPRID1 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- LIN9 | c.1275G>C p.M425I (on ENST00000366808 / NM_001270410.2; = p.M370I on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LRIG3 | c.2599A>T p.R867W | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRP1B | c.12995C>A p.S4332Y | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); called by muse, varscan2
- MANEA | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 71/321 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- MARCHF8 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAST2 | c.2270A>G p.D757G | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- MED14 | c.4331C>T p.A1444V | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH5 | c.805C>A p.L269M | Missense Mutation (SNP) | VAF 68/437 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR0B1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 221/438 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- NRK | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- NRXN1 | c.2930_2933del p.G977Afs*14 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | called by mutect2, pindel, varscan2
- ODF2L | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD4 | c.2388C>G p.I796M (on ENST00000447906 / NM_001366057.1; = p.I731M on NM_001102653.1) | Missense Mutation (SNP) | VAF 129/213 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PALB2 | c.3427C>A p.L1143I | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PCDHB15 | c.2299T>A p.L767M | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); called by muse, mutect2
- PCDHGA5 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 167/259 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PKD1 | c.9070G>A p.V3024M | Missense Mutation (SNP) | VAF 123/978 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLAGL2 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PPP1R3F | c.1270T>C p.C424R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- RFX6 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, varscan2
- RIPK4 | c.2330A>G p.D777G (on ENST00000352483; = p.D729G on NM_020639.3) | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- RUBCNL | c.147C>G p.H49Q | Missense Mutation (SNP) | VAF 103/391 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SAP30BP | c.152T>C p.F51S | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SENP7 | c.2047T>G p.C683G | Missense Mutation (SNP) | VAF 134/169 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SORCS3 | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 116/211 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SUGP1 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANC2 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 124/428 reads (29%) | called by muse, mutect2, varscan2
- TLE1 | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS11 | c.898C>G p.Q300E (on ENST00000620429; = p.Q844E on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- XIRP1 | c.2726C>G p.A909G | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- ZC3H18 | c.683T>G p.M228R | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ZNF420 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF600 | c.1022G>A p.W341* | Nonsense Mutation (SNP) | VAF 226/358 reads (63%) | called by muse, mutect2, varscan2
- ZNF660 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 30/262 reads (11%) | called by muse, mutect2, varscan2
- ZW10 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ACOXL | c.630C>T p.S210= | Silent (SNP) | VAF 93/179 reads (52%) | catalogued as rs776875130; called by muse, mutect2, varscan2
- ANKFN1 | c.3264C>T p.D1088= (on ENST00000653862; = p.D941= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 330/485 reads (68%) | catalogued as rs1297126836, COSV73718981; called by muse, mutect2, varscan2
- C3orf18 | c.210G>A p.T70= | Silent (SNP) | VAF 60/303 reads (20%) | catalogued as rs768800486, COSV99231943, COSV99232014; called by muse, mutect2, varscan2
- CELSR3 | c.3114C>T p.Y1038= | Silent (SNP) | VAF 58/291 reads (20%) | catalogued as rs778090405, COSV50882888; called by muse, mutect2, varscan2
- CES4A | c.489G>T p.V163= | Silent (SNP) | VAF 192/427 reads (45%) | called by muse, mutect2, varscan2
- CES4A | c.1029G>T p.V343= | Silent (SNP) | VAF 37/279 reads (13%) | called by muse, mutect2, varscan2
- CHRNB3 | c.519C>A p.S173= | Silent (SNP) | VAF 67/431 reads (16%) | called by muse, mutect2, varscan2
- COL22A1 | c.1518G>A p.P506= | Silent (SNP) | VAF 78/519 reads (15%) | catalogued as rs575514821, COSV57342112; called by muse, mutect2, varscan2
- CSF2RA | c.231C>T p.N77= | Silent (SNP) | VAF 437/584 reads (75%) | catalogued as rs767927197, COSV62623442; called by muse, mutect2, varscan2
- ENG | c.1329C>T p.L443= | Silent (SNP) | VAF 160/619 reads (26%) | catalogued as COSV61229076; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1386C>T p.H462= | Silent (SNP) | VAF 82/152 reads (54%) | catalogued as rs561419730; called by muse, mutect2, varscan2
- FLNA | c.210C>T p.D70= | Silent (SNP) | VAF 365/589 reads (62%) | called by muse, mutect2, varscan2
- GTF2A2 | c.99C>T p.A33= | Silent (SNP) | VAF 70/70 reads (100%) | called by muse, mutect2, varscan2
- HIPK1 | c.510C>T p.S170= | Silent (SNP) | VAF 87/210 reads (41%) | catalogued as rs368795005; called by muse, mutect2, varscan2
- IRX4 | c.93C>G p.G31= | Silent (SNP) | VAF 86/288 reads (30%) | called by muse, mutect2, varscan2
- PCDHB15 | c.2301G>A p.L767= | Silent (SNP) | VAF 62/183 reads (34%) | called by muse, mutect2
- PLXNA4 | c.1755G>A p.P585= | Silent (SNP) | VAF 171/545 reads (31%) | catalogued as rs749277155, COSV58142069; called by muse, mutect2, varscan2
- PRR32 | c.690G>A p.P230= | Silent (SNP) | VAF 179/353 reads (51%) | catalogued as rs1187927699, COSV100947888, COSV64420750; called by muse, mutect2, varscan2
- PRR33 | c.1326C>T p.N442= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as rs750539867; called by muse, mutect2, varscan2
- SKIV2L | c.1182C>T p.S394= | Silent (SNP) | VAF 39/187 reads (21%) | called by mutect2, varscan2
- SYT9 | c.81C>T p.H27= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as COSV100607733; called by muse, mutect2, varscan2
- TMEM132C | c.750C>T p.N250= | Silent (SNP) | VAF 56/89 reads (63%) | catalogued as rs775829161, COSV70659367; called by muse, mutect2, varscan2
- WDR45 | c.1047C>T p.D349= (on ENST00000376372 / NM_001029896.2; = p.D350= on NM_007075.3) | Silent (SNP) | VAF 98/239 reads (41%) | catalogued as rs376872853, COSV59876345; called by muse, mutect2, varscan2
- CCDC39 | chr3:180679793 C>T | 5'Flank (SNP) | VAF 10/79 reads (13%) | catalogued as rs1290651415; called by muse, mutect2, varscan2
- FOCAD | c.57+763T>G | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.78-2255C>T | Intron (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- GUSBP1 | n.180-10268C>A | Intron (SNP) | VAF 175/2768 reads (6%) | called by muse, mutect2
- MMADHC | c.-44_-43del | 5'UTR (DEL) | VAF 115/267 reads (43%) | called by mutect2, pindel, varscan2
- MYADML | n.996G>A | RNA (SNP) | VAF 82/365 reads (22%) | catalogued as rs750520177; called by muse, varscan2
- OR2H2 | chr6:29582314 T>A | 5'Flank (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- PMS2CL | n.1276G>A | RNA (SNP) | VAF 52/513 reads (10%) | catalogued as rs535681432; called by muse, mutect2
- PRSS30P | n.2781C>T | RNA (SNP) | VAF 156/290 reads (54%) | catalogued as rs778932607; called by muse, mutect2, varscan2
- TRPM6 | c.2238+49A>G | Intron (SNP) | VAF 119/206 reads (58%) | called by muse, mutect2, varscan2
- ZNRD2 | chr11:65569996 G>C | 5'Flank (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
